Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7261, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7261-01A (Primary Tumor).

[page 1 of 4]
***** **MODIFIED REPORT - REVIEW ADDENDUM SECTION** *****

DIAGNOSIS

- (A) RIGHT NECK DISSECTION, LEVEL II B:
Lymph node, no tumor present (0/1)
- (B) RIGHT NECK DISSECTION, LEVEL III B:
Lymph nodes, no tumor present (0/2)
- (C) RIGHT NECK DISSECTION, LEVEL II A:
Lymph nodes, no tumor present (0/6)
- (D) RIGHT NECK DISSECTION, LEVEL III A:
Lymph nodes, no tumor present (0/2)
- (E) TOTAL LARYNGECTOMY AND THYROIDECTOMY:
INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated
- Tumor Features:
- Gross: Ulcerating
- Size: 4.5 cm in largest dimension
- Invasion: Present, depth 1 cm
- Tumor Border: Infiltrative with thin cords < 4 cells
- Perineural Invasion: Absent
- Vascular Invasion: Absent
- Bone / Cartilage Invasion: Cartilage invasion Present
- Lymphocyte Infiltration: Moderate
- Thyroid, no tumor present
- (F) RIGHT PARATRACHEAL:
Lymph nodes, no tumor present (0/3)
- (G) RIGHT PARATRACHEAL MASS, EVALUATE FOR PARATHYROID:
Lymph nodes, no tumor present (0/1)
- (H) DEEP NODES, RIGHT NECK DISSECTION, LEVEL IV:
Lymph nodes, no tumor present (0/2)

GROSS DESCRIPTION

[page 2 of 4]
(A) RIGHT NECK DISSECTION, LEVEL II B - One possible lymph node, 1.5 x 0.2 cm. Entirely submitted in A. [REDACTED]
(B) RIGHT NECK DISSECTION, LEVEL III B - Fibroadipose tissue, 2.2 x 1.2 x 0.6 cm. Four possible lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 cm to 0.4 x 0.3 x 0.2 cm.

SECTION CODE: B1, four possible lymph nodes; B2, remainder of fibroadipose tissue entirely submitted. [REDACTED]

(C) RIGHT NECK DISSECTION, LEVEL II A - Fibroadipose tissue, 2.5 x 2.5 x 1.2 cm. Six lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 to 1.2 x 0.6 x 0.5 cm.

SECTION CODE: C1, two lymph nodes; C2, three lymph nodes; C3, one lymph node serially sectioned. [REDACTED]

(D) RIGHT NECK DISSECTION, LEVEL III A - Fibroadipose tissue and muscle, 4.5 x 2.8 x 1.3 cm. Two lymph nodes (0.7 x 0.4 x 0.3 and 1.0 x 0.6 x 0.3 cm) are identified and submitted in D. [REDACTED]

(E) TOTAL LARYNGECTOMY AND THYROIDECTOMY - The specimen (overall measuring 12.1 x 9.5 x 3.5 cm) consists of hyoid bone, larynx and trachea (11.5 cm in length, 4.5 cm in circumference), anterior soft tissue (9.7 x 5.5 x 1.2 cm, including skeletal muscle and fibroconnective tissue), and right thyroid lobe (4.2 x 3.7 x 1.5 cm).

Centrally located at ventricle is an ulcerated circumferential tumor (3.9 in length, 4.5 cm in circumference). The tumor extends 2.5 cm superior to supraepiglottis and 1.3 cm inferior to subepiglottis. The tumor invades through the cricoid cartilage with a maximum depth of 0.7 cm. The tumor appears to abut the thyroid cartilage. The anterior soft tissue and right thyroid are not involved by the tumor. The tumor is 2.7 cm from the tracheal resection margin and 0.8 cm from the closest aryepiglottic fold (left lateral). Sections of thyroid cartilage and cricoid cartilage are submitted for decalcification. The thyroid cartilage are submitted to bone lab for decalcification and additional sections. Representative sections of the tumor and normal mucosa are submitted to tissue bank.

SECTION CODE: E1-E5, frozen section (E1, left lateral mucosal margin; E2, posterior mucosal margin, E3, right lateral mucosal margin, E4, E5, entire tracheal resection margin); E6, posterior, tumor and subglottis; E7, posterior, tumor and supraglottis; E8, left, tumor and subglottis; E9, left, tumor and supraglottis; E10, anterior, tumor and subglottis; E11, anterior, tumor and supraglottis; E12, right, tumor and subglottis; E13, right, tumor and supraglottis; E14, tumor and cricoid cartilage; E15, thyroid cartilage; E16, representative section of thyroid and a possible parathyroid; E17, representative section of anterior soft tissue; E18-E21, representative cross section of the bony and cartilaginous tissue associated with tumor, submitted for decalcification [REDACTED]

*FS/DX: LEFT LATERAL MUCOSAL MARGIN, RIGHT LATERAL MUCOSAL MARGIN, RIGHT LATERAL MUCOSAL MARGIN, ENTIRE TRACHEAL MARGIN. MARGINS NEGATIVE FOR CARCINOMA. [REDACTED]

(F) RIGHT PARATRACHEAL - Fibroadipose tissue, 1.5 x 1.5 x 0.8 cm. One lymph node, 0.4 x 0.3 x 0.3 cm is identified.

SECTION CODE: F1, one lymph node; F2, remainder of fibroadipose tissue entirely submitted. [REDACTED]

(G) RIGHT PARATRACHEAL MASS, EVALUATE FOR PARATHYROID - Two tan-pink soft tissue fragments, 0.1 x 0.1 x 0.1 cm each and weigh 0.0011 g in toto. Submitted entirely in G for frozen section. Touch preps are performed. [REDACTED]

*FS/DX: LYMPH NODE NEGATIVE FOR TUMOR. [REDACTED]

(H) DEEP NODES, RIGHT NECK DISSECTION, LEVEL IV - Two lymph nodes (0.1 x 0.1 x 0.1 and 0.5 x 0.3 x 0.1 cm) are identified and entirely submitted in H. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-24100, M-80703, M-43000,

[page 3 of 4]
Entire report and diagnosis completed by:

Page 3 of 4	
Surgical Pathology Report	
File under: Pathology	

[page 4 of 4]
ADDENDUM

This modified report is being issued to provide additional results.

DIAGNOSIS

(E) TOTAL LARYNGECTOMY AND THYROIDECTOMY:
INVASIVE SQUAMOUS CARCINOMA INVADING INTO BONE.

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 4 of 4
File under: Pathology		

Source: NCI Genomic Data Commons file 9db680f6-544e-4e37-8603-3a30d447c2fc (TCGA-CV-7261.FC829564-A133-4366-BBF2-5523C7E064CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).